Somatic mutation profile of tumor specimen 0DSG25 from CCDI case PBCICB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 6.1 years (2,215 days).
Specimen 0DSG25: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8eff447-081c-46cb-a87a-98512171be95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSG2M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/332c77c9-5a3d-4330-85f1-df7434f651f8

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 351/836 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 31/706 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2
- KCNAB1 | c.1048C>T p.R350C (on ENST00000490337 / NM_172160.3; = p.R339C on NM_003471.3) | Missense Mutation (SNP) | VAF 69/975 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs750605362, COSV100204771; called by muse, mutect2
- OR2T2 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 320/2120 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV100737586; called by mutect2, varscan2
- PSEN2 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 185/640 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs149354305; ClinVar: uncertain significance; called by mutect2, varscan2
- SMARCA4 | c.3484G>A p.G1162S | Missense Mutation (SNP) | VAF 45/1005 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100759311, COSV60788440, COSV60801054; called by muse, mutect2
- AL662899.2 | c.65_67del p.F22del | In Frame Del (DEL) | VAF 28/270 reads (10%) | called by pindel, varscan2
- CSNK2B | c.368-3C>G | Splice Region (SNP) | VAF 133/247 reads (54%) | called by muse, mutect2, varscan2
- MUC12 | c.12481G>A p.G4161S (on ENST00000379442; = p.G4018S on NM_001164462.1) | Missense Mutation (SNP) | VAF 96/1259 reads (8%) | SIFT tolerated (0.95); called by muse, mutect2
- PPIL2 | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- FSIP2 | c.2178C>G p.L726= | Silent (SNP) | VAF 78/1924 reads (4%) | called by muse, mutect2
- NRXN2 | c.4347C>T p.F1449= | Silent (SNP) | VAF 75/286 reads (26%) | catalogued as rs1196145390; called by muse, mutect2, varscan2
- SPECC1 | c.429T>C p.P143= | Silent (SNP) | VAF 102/1064 reads (10%) | catalogued as COSV54958435; called by muse, mutect2
- PCDHGA8 | c.2424+71dup | Intron (INS) | VAF 90/466 reads (19%) | called by mutect2, pindel, varscan2
- PPHLN1 | c.1125+21C>T | Intron (SNP) | VAF 184/661 reads (28%) | catalogued as rs367843121; called by muse, mutect2, varscan2
